Gene-level copy-number profile of tumor specimen TCGA-24-2020-01A from TCGA case TCGA-24-2020, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.6 years (24,682 days).
Specimen TCGA-24-2020-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.354d346e-f49a-410e-90fc-073cd4977286.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-2020-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8a1aefbc-5815-4a0d-a411-f2d4d8f9855c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 2: 4,226; copy number 3: 11,184; copy number 4: 15,572; copy number 5: 6,463; copy number 6: 11,523; copy number 7: 2,963; copy number 8: 3,863; copy number 9: 1,755; copy number 10: 920; copy number 11: 327; copy number 12: 293; copy number 13: 597; copy number 14: 121.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-2020-01): tumor purity 0.95, ploidy 5, whole-genome doublings 2 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:78,355,529–78,553,296, 5 genes: LSM3P5, AC046158.1, AC046158.4, AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 4,013 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,523,514–113,901,237, 34 genes, copy number 11 (within-gene range 8–11): ST7L, CAPZA1, MRPL53P1, RNU7-70P, MOV10, AL603832.1, RHOC, AL603832.3, PPM1J, AL603832.2, TAFA3, NUTF2P4, LINC01356, LINC01357, AL390729.1, SLC16A1, AKR7A2P1, SLC16A1-AS1, AL390242.1, LRIG2-DT, LRIG2, RLIMP2, AL357055.1, AL357055.2, MAGI3, AL391058.1, MTND5P20, PHTF1, AL133517.1, RSBN1, AL137856.1, PTPN22, AP4B1-AS1, BCL2L15.
- chr1:115,270,767–121,580,524, 148 genes, copy number 10 (broad region; genes not listed).
- chr1:147,099,482–147,993,592, 25 genes, copy number 11 (within-gene range 7–11): NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B.
- chr1:172,775,905–191,228,467, 301 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr1:229,087,114–229,205,428, 1 gene, copy number 9: LINC02814.
- chr3:144,442,211–193,844,024, 774 genes, copy number 10–14 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 10–14 (broad region; genes not listed).
- chr5:91,223,419–91,281,643, 5 genes, copy number 9: AC093281.1, AC093281.2, RNU4-90P, AC123595.1, AC123595.2.
- chr9:7,914,514–7,961,224, 2 genes, copy number 9: AL135923.2, AL135923.1.
- chr10:125,162,379–133,761,125, 153 genes, copy number 10 (broad region; genes not listed).
- chr11:49,405,091–50,422,316, 35 genes, copy number 9: TYRL, CBX3P8, AC135977.1, AC136759.1, AC130364.1, AC130364.2, TRIM51FP, AP006587.5, AP006587.6, AP006587.4, AP006587.3, TRIM51DP, AP006587.1, AP006587.2, OR4A1P, OR4A49P, OR4A18P, OR4A19P, OR4R3P, OR4C13, OR4C12, OR4C48P, OR4C45, OR4C49P, GTF2IP11, AC109635.3, AC109635.6, AC109635.5, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr12:112,978,395–113,438,276, 20 genes, copy number 9: OAS2, IMMP1LP2, RPS15AP32, DTX1, RASAL1, CFAP73, Y_RNA, DDX54, MIR7106, Y_RNA, RITA1, AC089999.1, IQCD, TPCN1, AC089999.2, MIR6762, SLC8B1, PLBD2, SDS, SDSL.
- chr17:66,197,693–66,278,664, 4 genes, copy number 12: PSMD7P1, APOH, RNA5SP444, AC009452.1.
- chr19:27,638,483–30,060,797, 61 genes, copy number 10–13 (broad region; genes not listed).
- chr19:39,236,433–50,066,793, 627 genes, copy number 9 (broad region; genes not listed).
- chr20:87,250–39,349,392, 857 genes, copy number 9–11 (broad region; genes not listed).
- chr20:47,160,838–47,493,085, 10 genes, copy number 10: AL022342.1, MIR3616, ZMYND8, AL031666.2, AL031666.3, AL031666.1, LINC01754, RPL35AP, RNU6-497P, RNU6-563P.
- chr20:50,930,984–63,216,139, 246 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
